Somatic mutation profile of tumor specimen ALCH-B5WH-TTP1-A (aliquot ALCH-B5WH-TTP1-A-1-0-D-A87U-36) from ALCHEMIST case ALCH-B5WH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,189 days).
Specimen ALCH-B5WH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0ea8b97-98e4-4a66-b72b-d3d5bba91d46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5WH-NB1-A (Blood Derived Normal), aliquot ALCH-B5WH-NB1-A-1-0-D-A87U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01def268-0a42-4474-902e-6da3fb4e6080

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Intron 5, Frame Shift Del 2, Nonsense Mutation 2, Translation Start Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.1478C>T p.T493M (on ENST00000326724 / NM_001080395.3; = p.T390M on NM_004920.2) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58692122; called by muse, mutect2, varscan2
- CHD8 | c.5593G>A p.G1865R (on ENST00000646647 / NM_001170629.2; = p.G1586R on NM_020920.4) | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); catalogued as rs1171191926; called by muse, mutect2
- FIG4 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368625871; ClinVar: uncertain significance; called by muse, varscan2
- HTR2C | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.543); catalogued as COSV99349573; called by muse, mutect2, varscan2
- KLF17 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145084649, COSV64856733; called by muse, mutect2
- MUC4 | c.9959C>T p.S3320L | Missense Mutation (SNP) | VAF 42/478 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.316); catalogued as rs148923966; called by muse, mutect2
- NETO1 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 33/248 reads (13%) | catalogued as COSV55006446; called by muse, mutect2, varscan2
- P3H1 | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as rs1490385120; called by muse, mutect2
- PGK1 | c.412A>G p.N138D | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1275482552; called by muse, mutect2
- SEZ6L2 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.209); catalogued as COSV100435313; called by muse, mutect2, varscan2
- ANKRD55 | c.456del p.S153Afs*11 | Frame Shift Del (DEL) | VAF 8/103 reads (8%) | called by mutect2, varscan2
- AP1M2 | c.688T>C p.S230P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CCDC130 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2
- CHD8 | c.6682G>A p.E2228K (on ENST00000646647 / NM_001170629.2; = p.E1949K on NM_020920.4) | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CHD8 | c.2225A>C p.E742A (on ENST00000646647 / NM_001170629.2; = p.E463A on NM_020920.4) | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, varscan2
- CTNNA1 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DNPEP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/154 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by mutect2, varscan2
- ENTPD7 | c.1193C>G p.A398G | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.281); called by muse, mutect2
- EWSR1 | c.1188_1204del p.M397Gfs*16 | Frame Shift Del (DEL) | VAF 11/122 reads (9%) | called by mutect2, pindel
- HUWE1 | c.7262G>A p.S2421N | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); called by muse, varscan2
- LIPN | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MARK2 | c.2291G>A p.R764Q (on ENST00000402010 / NM_001039469.2; = p.R700Q on NM_004954.5) | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MN1 | c.3083T>A p.L1028Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NOL6 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 41/315 reads (13%) | called by muse, mutect2, varscan2
- PCID2 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- PDZD2 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB4 | c.2672C>G p.S891C | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2
- PTPRF | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PUF60 | c.742G>C p.A248P (on ENST00000526683 / NM_001362896.2; = p.A231P on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- SCNN1A | c.948_953del p.W317_M318del | In Frame Del (DEL) | VAF 20/233 reads (9%) | called by mutect2, pindel
- SEC24B | c.1895T>A p.V632E | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- SUCLG1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM161A | c.1319G>T p.G440V | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TMEM253 | c.601A>T p.N201Y | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- TMEM62 | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF423 | c.3221G>T p.C1074F (on ENST00000563137 / NM_001379286.1; = p.C1066F on NM_015069.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD8 | c.6480G>A p.L2160= (on ENST00000646647 / NM_001170629.2; = p.L1881= on NM_020920.4) | Silent (SNP) | VAF 12/80 reads (15%) | called by mutect2, varscan2
- LCE2D | c.42C>A p.P14= | Silent (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- NLRP13 | c.690G>A p.T230= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as rs574504902, COSV61619992; called by muse, mutect2
- OR2M7 | c.642C>T p.I214= | Silent (SNP) | VAF 33/305 reads (11%) | called by muse, mutect2, varscan2
- PEG3 | c.4509A>G p.P1503= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as rs1035781751; called by muse, mutect2
- PPP1R37 | c.1335C>T p.A445= | Silent (SNP) | VAF 48/295 reads (16%) | catalogued as rs773605941; called by muse, mutect2, varscan2
- SALL4 | c.750C>T p.S250= | Silent (SNP) | VAF 17/299 reads (6%) | catalogued as rs1041145698; called by muse, mutect2
- SCN9A | c.2649C>G p.V883= (on ENST00000303354; = p.V872= on NM_002977.3) | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as rs200618289; called by muse, mutect2
- TBXA2R | c.426G>A p.A142= | Silent (SNP) | VAF 26/463 reads (6%) | called by muse, mutect2
- TMEM62 | c.990A>T p.P330= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- ZFR2 | c.2295C>T p.C765= | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as COSV99507692; called by muse, mutect2, varscan2
- CRYZL1 | c.-7+462C>T | Intron (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- DCUN1D5 | c.86+75C>A | Intron (SNP) | VAF 15/354 reads (4%) | called by muse, mutect2
- EML2 | c.1254+127G>C | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- POLR1D | c.-44C>T | 5'UTR (SNP) | VAF 14/242 reads (6%) | catalogued as rs1440411178; called by muse, mutect2
- SCARB2 | c.825-10A>G | Intron (SNP) | VAF 27/177 reads (15%) | catalogued as rs1233610339; called by muse, mutect2, varscan2
- SPATA20 | c.77+437G>A | Intron (SNP) | VAF 22/437 reads (5%) | catalogued as COSV50068365; called by muse, mutect2
